Somatic mutation profile of tumor specimen C3L-00369-01 (aliquot CPT0006440009) from CPTAC case C3L-00369, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-00369-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21593bef-3c3c-4610-8775-431ac73eea9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00369-31 (Blood Derived Normal), aliquot CPT0002660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/954eea95-0254-4a4f-ac18-846162f341a9

The open-access MAF lists 126 somatic variants for this specimen: 89 protein-altering or splice-affecting, 18 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 18, Intron 11, Frame Shift Del 11, Frame Shift Ins 8, Nonsense Mutation 3, Splice Region 3, 3'UTR 2, RNA 2, Splice Site 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSS1 | c.197dup p.X66_splice | Splice Site (INS) | VAF 174/448 reads (39%) | catalogued as rs760706338; called by mutect2, pindel, varscan2
- ANGPTL1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.146); catalogued as COSV52367273; called by muse, mutect2, varscan2
- AOC1 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs759480873, COSV62870757; called by muse, mutect2, varscan2
- CCDC42 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 196/704 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1424864420; called by muse, varscan2
- CNGA3 | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 523/1324 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.595); catalogued as CM014556; called by muse, mutect2, varscan2
- CUX2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs374906688; called by muse, mutect2, varscan2
- DNMT3A | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 111/340 reads (33%) | catalogued as rs1449820788, COSV53051427; called by muse, mutect2, varscan2
- FAM167A | c.246G>T p.L82F | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1237350309; called by muse, mutect2, varscan2
- FAT4 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 203/521 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs745757322; called by muse, mutect2, varscan2
- GP9 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 546/1420 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as rs745846700, COSV100264665; called by muse, mutect2, varscan2
- KRT13 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 252/628 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs746117318, COSV55839059; called by muse, mutect2, varscan2
- LRRC53 | c.890T>C p.V297A | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1026472696; called by muse, mutect2
- P2RX7 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 50/644 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as rs769375378; called by muse, mutect2
- POLQ | c.3697G>A p.V1233I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs1560097578; called by muse, mutect2, varscan2
- SLC27A1 | c.1308G>C p.Q436H | Missense Mutation (SNP) | VAF 33/492 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as rs142834494; called by muse, mutect2
- SMARCA4 | c.3466A>G p.T1156A | Missense Mutation (SNP) | VAF 326/801 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100759360; called by muse, mutect2, varscan2
- SPEG | c.8081C>T p.A2694V | Missense Mutation (SNP) | VAF 85/684 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.106); catalogued as rs1359968361; called by muse, mutect2, varscan2
- SPTBN2 | c.6745G>A p.V2249I | Missense Mutation (SNP) | VAF 350/928 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs774816936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM132C | c.2536G>A p.V846M | Missense Mutation (SNP) | VAF 157/397 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs780371502; called by muse, mutect2, varscan2
- TTN | c.93650A>C p.K31217T (on ENST00000591111; = p.K23793T on NM_003319.4) | Missense Mutation (SNP) | VAF 55/178 reads (31%) | PolyPhen possibly damaging (0.801); catalogued as rs1322355821; called by muse, mutect2, varscan2
- VHL | c.512del p.K171Sfs*31 | Frame Shift Del (DEL) | VAF 229/384 reads (60%) | catalogued as COSV56544879; called by mutect2, pindel, varscan2
- YIPF5 | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV50823145; called by muse, mutect2, varscan2
- ADGRE5 | c.1912T>C p.Y638H (on ENST00000242786 / NM_078481.4; = p.Y545H on NM_001784.5) | Missense Mutation (SNP) | VAF 354/903 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADH6 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- AFDN | c.821del p.A274Efs*9 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- ALKBH6 | c.614C>A p.P205Q (on ENST00000252984 / NM_001297701.2; = p.P233Q on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ALMS1 | c.1646A>C p.E549A | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ANKS1A | c.791A>C p.Q264P | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARHGAP30 | c.566A>C p.N189T | Missense Mutation (SNP) | VAF 236/553 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP36 | c.1180_1181insAG p.G394Efs*26 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- ATP6V0A1 | c.2248+1G>A p.X750_splice (on ENST00000343619 / NM_001378531.1; = p.X744_splice on NM_005177.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 187/441 reads (42%) | called by muse, mutect2, varscan2
- BCL2L14 | c.15del p.S5Rfs*10 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- BIVM-ERCC5 | c.3917_3918dup p.N1307* | Frame Shift Ins (INS) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- BSPRY | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 314/766 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CARMIL2 | c.1824T>G p.N608K | Missense Mutation (SNP) | VAF 337/818 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CARMIL3 | c.3547_3556del p.G1183Rfs*42 | Frame Shift Del (DEL) | VAF 85/410 reads (21%) | called by mutect2, pindel, varscan2
- CATSPERB | c.3258G>A p.W1086* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- CCDC114 | c.156del p.L53Wfs*8 | Frame Shift Del (DEL) | VAF 256/742 reads (35%) | called by mutect2, pindel, varscan2
- CCDC141 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CEBPA | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 651/1545 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP44 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- CHD9 | c.7657A>C p.N2553H (on ENST00000398510 / NM_001382353.1; = p.N2537H on NM_025134.7) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLUL1 | c.1294T>G p.F432V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CNOT7 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CR2 | c.2830G>A p.G944R | Missense Mutation (SNP) | VAF 91/284 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DHRS4 | c.74C>G p.T25S | Missense Mutation (SNP) | VAF 170/591 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMGDH | c.1620_1621dup p.N541Ifs*28 | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | called by mutect2, varscan2
- DNAH14 | c.9239T>G p.I3080S (on ENST00000445597; = p.I4088S on NM_001367479.1) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- DOCK9 | c.190A>C p.I64L (on ENST00000376460 / NM_001366676.2; = p.I65L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- DOT1L | c.1045A>G p.S349G | Missense Mutation (SNP) | VAF 110/358 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EBF3 | c.154del p.A52Rfs*80 | Frame Shift Del (DEL) | VAF 137/378 reads (36%) | called by mutect2, pindel, varscan2
- ELAC2 | c.404A>C p.K135T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- EXPH5 | c.2688T>G p.D896E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GANC | c.1606dup p.E536Gfs*26 | Frame Shift Ins (INS) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- GRSF1 | c.362C>A p.S121Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); called by mutect2, varscan2
- GTF2I | c.1750+9_1750+10dup | Splice Region (INS) | VAF 44/329 reads (13%) | called by mutect2, pindel, varscan2
- KLHL7 | c.50A>T p.K17I | Missense Mutation (SNP) | VAF 435/1147 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- LRRC37B | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 133/329 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MAML1 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 463/1193 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MAPK1IP1L | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 233/526 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- MTHFS | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 220/472 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NEK5 | c.1753T>A p.L585I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- NOM1 | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- OR3A2 | c.772_774del p.C258del | In Frame Del (DEL) | VAF 105/312 reads (34%) | called by mutect2, pindel, varscan2
- PITRM1 | c.2531_2532insCAC p.M844delinsIT | Splice Region (INS) | VAF 128/344 reads (37%) | called by mutect2, varscan2
- PITRM1 | c.2527_2529dup p.V843dup | In Frame Ins (INS) | VAF 154/390 reads (39%) | called by mutect2*, pindel, varscan2*
- PKHD1L1 | c.2368T>G p.Y790D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLAGL1 | c.969_982del p.K323Nfs*5 | Frame Shift Del (DEL) | VAF 42/190 reads (22%) | called by pindel, varscan2
- PLCD1 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 301/465 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- PRDM5 | c.394_395insC p.E132Afs*16 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by mutect2, pindel
- PRTG | c.1487del p.Y496Lfs*13 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- RAB3GAP1 | c.1557G>A p.M519I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RPN2 | c.1333C>G p.Q445E | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SH2D4B | c.1261C>A p.Q421K (on ENST00000646907; = p.T346K on NM_207372.2) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SKOR1 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.039); called by muse, mutect2
- SLC12A2 | c.1868_1869insTG p.K624Afs*35 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- SMTNL2 | c.1221G>T p.Q407H (on ENST00000389313 / NM_001114974.2; = p.Q263H on NM_198501.3) | Missense Mutation (SNP) | VAF 205/533 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SNAI1 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 190/371 reads (51%) | called by muse, mutect2, varscan2
- SPEN | c.4085_4088del p.R1362Ifs*46 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- SYPL1 | c.692_693insA p.F231Lfs*19 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- TDRD10 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 157/394 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMEM131L | c.3494C>T p.S1165L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAP1 | c.491C>A p.T164K | Missense Mutation (SNP) | VAF 211/607 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- UBXN2A | c.150del p.K50Nfs*12 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- USP53 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- WDR87 | c.129G>A p.Q43= | Splice Region (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- ZBED5 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDBF2 | c.3347dup p.L1116Ffs*6 | Frame Shift Ins (INS) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- ZNF106 | c.408del p.D137Mfs*15 | Frame Shift Del (DEL) | VAF 51/140 reads (36%) | called by mutect2, pindel, varscan2
- BTBD18 | c.495C>A p.T165= | Silent (SNP) | VAF 230/575 reads (40%) | called by muse, mutect2, varscan2
- C5orf15 | c.69C>T p.I23= | Silent (SNP) | VAF 419/1041 reads (40%) | catalogued as rs747208047, COSV51548789; called by muse, mutect2, varscan2
- COL6A3 | c.9402C>T p.T3134= | Silent (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- CYGB | c.132C>T p.A44= | Silent (SNP) | VAF 327/864 reads (38%) | called by muse, mutect2, varscan2
- FREM3 | c.3930T>C p.T1310= | Silent (SNP) | VAF 34/93 reads (37%) | called by muse, mutect2, varscan2
- HDAC6 | c.3468C>T p.Y1156= | Silent (SNP) | VAF 101/147 reads (69%) | called by muse, mutect2, varscan2
- KLHL17 | c.1887G>T p.P629= | Silent (SNP) | VAF 271/642 reads (42%) | called by muse, mutect2, varscan2
- KXD1 | c.85C>T p.L29= | Silent (SNP) | VAF 150/465 reads (32%) | called by muse, mutect2, varscan2
- MROH2B | c.808A>C p.R270= | Silent (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- MYH13 | c.1755C>T p.A585= | Silent (SNP) | VAF 212/554 reads (38%) | catalogued as rs1040817237; called by muse, mutect2, varscan2
- PCARE | c.2349T>A p.I783= | Silent (SNP) | VAF 67/170 reads (39%) | catalogued as COSV100527871; called by muse, mutect2, varscan2
- PKP3 | c.118C>A p.R40= | Silent (SNP) | VAF 132/355 reads (37%) | catalogued as rs1052027375; called by muse, mutect2, varscan2
- POP1 | c.1968G>A p.S656= | Silent (SNP) | VAF 66/262 reads (25%) | catalogued as rs1203972400, COSV100855814; called by muse, mutect2, varscan2
- RAB6A | c.411A>T p.S137= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- REC8 | c.228T>G p.G76= | Silent (SNP) | VAF 186/591 reads (31%) | called by muse, mutect2, varscan2
- SUFU | c.1440C>T p.D480= | Silent (SNP) | VAF 462/1173 reads (39%) | called by muse, mutect2, varscan2
- ZBP1 | c.498C>T p.R166= | Silent (SNP) | VAF 122/307 reads (40%) | called by muse, mutect2, varscan2
- ZNF582 | c.762G>A p.P254= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs200288756; called by muse, mutect2, varscan2
- ABCA11P | n.942T>G | RNA (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.858+35A>G | Intron (SNP) | VAF 392/1030 reads (38%) | called by muse, varscan2
- ARGLU1 | c.573+20A>G | Intron (SNP) | VAF 20/256 reads (8%) | called by muse, mutect2
- ARHGDIA | c.*259C>G | 3'UTR (SNP) | VAF 38/420 reads (9%) | called by muse, mutect2
- FAM160A2 | c.2215+211G>T | Intron (SNP) | VAF 44/107 reads (41%) | called by muse, mutect2, varscan2
- HERC2P3 | n.877C>T | RNA (SNP) | VAF 62/2441 reads (3%) | called by muse, mutect2
- LEO1 | c.1896+11dup | Intron (INS) | VAF 32/89 reads (36%) | called by mutect2, pindel, varscan2
- MEAK7 | c.153+453C>A | Intron (SNP) | VAF 98/247 reads (40%) | called by muse, mutect2, varscan2
- MIOX | c.341-11C>G | Intron (SNP) | VAF 185/429 reads (43%) | called by muse, mutect2, varscan2
- MYBL1 | c.-5G>A | 5'UTR (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2
- NPIPA7 | chr16:16374438 G>A | 5'Flank (SNP) | VAF 190/1037 reads (18%) | catalogued as rs757063145; called by muse, mutect2, varscan2
- NPIPA7 | chr16:16374439 C>T | 5'Flank (SNP) | VAF 189/1035 reads (18%) | catalogued as rs1370785882; called by muse, mutect2, varscan2
- PLCXD2 | c.*19A>T | 3'UTR (SNP) | VAF 61/137 reads (45%) | called by muse, mutect2, varscan2
- POLR3E | c.87+235G>T | Intron (SNP) | VAF 81/240 reads (34%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948675 T>C | 3'Flank (SNP) | VAF 276/1088 reads (25%) | catalogued as rs1044877; called by muse, mutect2, varscan2
- RAB21 | c.220-37_220-33del | Intron (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- TCF4 | c.305-168T>C | Intron (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.308-26C>G | Intron (SNP) | VAF 258/674 reads (38%) | called by muse, mutect2, varscan2
- TPM1 | c.564-34T>C | Intron (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
